Somatic mutation profile of tumor specimen 5557e478-3e6f-475b-8acc-1b4159 (aliquot 5557e478-3e6f-475b-8acc-1b4159_D6) from CPTAC case 11CO077, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 5557e478-3e6f-475b-8acc-1b4159: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 838d236c-df44-43e7-a1ab-4ea54a9a7115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen dee0705e-34e8-467b-a5f6-b3678c (Blood Derived Normal), aliquot dee0705e-34e8-467b-a5f6-b3678c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7a36eac-4251-47d6-8c7c-14424367322b

The open-access MAF lists 159 somatic variants for this specimen: 104 protein-altering or splice-affecting, 36 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 36, Nonsense Mutation 14, Intron 9, RNA 8, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, 5'UTR 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 96/257 reads (37%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 158/469 reads (34%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2255C>T p.P752L (on ENST00000372530 / NM_001198934.2; = p.P724L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs770288857; called by muse, mutect2
- AGO1 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV64594859; called by muse, mutect2, varscan2
- APOH | c.604+1G>T p.X202_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as rs111559858; called by muse, mutect2
- ATP7B | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54438406; called by muse, mutect2
- BSN | c.7804C>T p.R2602C | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757590343; called by muse, mutect2, varscan2
- CABP5 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138142491; called by muse, mutect2, varscan2
- CACNB3 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1317239346; called by muse, mutect2
- CADM1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs201626870, COSV59008985; called by muse, mutect2, varscan2
- CHST8 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs538795960, COSV52859119; called by muse, mutect2, varscan2
- CNTNAP2 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.359); catalogued as rs143256141; called by muse, mutect2, varscan2
- CSMD1 | c.7663+1G>A p.X2555_splice (on ENST00000520002; = p.X2554_splice on NM_033225.6) | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as rs747720579, COSV59289275; called by muse, mutect2, varscan2
- CST3 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750555631; called by muse, mutect2, varscan2
- DIDO1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 188/398 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV56633037; called by muse, mutect2, varscan2
- DNAH17 | c.10471G>A p.E3491K | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752894740, COSV67750374; called by muse, mutect2, varscan2
- EEF2 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756996547; called by muse, mutect2, varscan2
- EMID1 | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.181); catalogued as rs1203095390; called by muse, mutect2, varscan2
- EPPK1 | c.5074G>A p.D1692N | Missense Mutation (SNP) | VAF 93/561 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs535303334, COSV73261359; called by muse, mutect2, varscan2
- GMPPB | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1512206; called by muse, mutect2, varscan2
- GORAB | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV63026669; called by muse, mutect2, varscan2
- GPR158 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747936646, COSV66270630; called by muse, mutect2, varscan2
- KANK1 | c.2318G>C p.G773A | Missense Mutation (SNP) | VAF 9/278 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100619440; called by muse, mutect2
- LACC1 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 8/192 reads (4%) | catalogued as COSV57829614; called by muse, mutect2
- LARP1 | c.592C>T p.R198C (on ENST00000518297 / NM_033551.3; = p.R121C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs768578356; called by muse, mutect2, varscan2
- MTSS2 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs763375984; called by muse, mutect2, varscan2
- NOL10 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776781129; called by muse, mutect2, varscan2
- OR2T4 | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 77/757 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63544587; called by muse, mutect2, varscan2
- OR51V1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs774588813, COSV58315645; called by muse, mutect2, varscan2
- OR6J1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 33/198 reads (17%) | catalogued as rs1034502918; called by muse, mutect2, varscan2
- PCDHB2 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 28/610 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV50580029; called by muse, mutect2
- PCNX3 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1370821475; called by muse, mutect2
- PDCL2 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs771112703, COSV55260154; called by muse, mutect2, varscan2
- PHACTR3 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 22/408 reads (5%) | catalogued as rs780579523, COSV63031154; called by muse, mutect2
- PIK3CG | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63250575; called by muse, mutect2
- QRFPR | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 44/262 reads (17%) | catalogued as rs767056594, COSV57676046; called by muse, mutect2, varscan2
- RBM6 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1306054670; called by muse, mutect2, varscan2
- REPIN1 | c.1326G>C p.Q442H | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV68292540; called by muse, mutect2
- SDK1 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757033817; called by muse, mutect2, varscan2
- SDK2 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs557765754, COSV66189854; called by muse, mutect2, varscan2
- SLC25A12 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1379335340; called by muse, mutect2
- SMOX | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255260823, COSV53865963; called by muse, mutect2
- TMPRSS11B | c.774dup p.H259Sfs*2 | Frame Shift Ins (INS) | VAF 19/147 reads (13%) | catalogued as rs1450492191; called by mutect2, pindel, varscan2
- TREML2 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101530186; called by muse, mutect2
- UGT3A2 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); catalogued as rs1383757582; called by muse, mutect2, varscan2
- ABLIM2 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- ACSBG2 | c.1347T>G p.C449W | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRB3 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2
- AKAP11 | c.4183_4187del p.M1395Pfs*32 | Frame Shift Del (DEL) | VAF 19/168 reads (11%) | called by mutect2, pindel, varscan2
- APC | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2
- ATG3 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMTA1 | c.3622C>T p.P1208S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CARD14 | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CDR2L | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CNTN6 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2
- COL14A1 | c.2306A>G p.Y769C | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTSE | c.922G>T p.A308S (on ENST00000360218; = p.A303S on NM_001910.4) | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCLRE1C | c.629A>C p.Y210S (on ENST00000378278 / NM_001350965.2; = p.Y95S on NM_022487.4) | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DMRTA2 | c.256A>T p.K86* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- EPHB6 | c.518_522del p.S173Ffs*150 | Frame Shift Del (DEL) | VAF 46/382 reads (12%) | called by mutect2, pindel
- ETS1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EYA2 | c.1134G>T p.R378S | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FAM131B | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 113/406 reads (28%) | called by muse, mutect2, varscan2
- FAT4 | c.11093A>T p.N3698I | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- FCGBP | c.7111T>C p.C2371R | Missense Mutation (SNP) | VAF 61/960 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FUT5 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2
- GDI2 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.296); called by muse, mutect2
- GGA1 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- GOLGA6L2 | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- GOSR1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); called by mutect2, varscan2
- GPAT2 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GTDC1 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- HCN1 | c.1780A>G p.I594V | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HECTD4 | c.4949C>A p.P1650H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFI16 | c.680T>G p.I227R | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAG1 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- KIF5A | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- L3MBTL1 | c.491C>A p.P164H (on ENST00000418998 / NM_001377303.1; = p.P74H on NM_015478.7) | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- LAMA2 | c.5365C>A p.L1789I | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMX1B | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRCH2 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRRC49 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- LZTS1 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MAP10 | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NPM2 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- OR5B17 | c.180dup p.L61Sfs*3 | Frame Shift Ins (INS) | VAF 30/238 reads (13%) | called by mutect2, pindel, varscan2
- OSGIN2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PCDHB5 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 41/382 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PRMT7 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- RAB3IP | c.1198C>A p.Q400K (on ENST00000550536 / NM_175623.4; = p.Q384K on NM_022456.5) | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RBM12 | c.1909_1911del p.K637del | In Frame Del (DEL) | VAF 65/349 reads (19%) | called by mutect2, varscan2
- RP1L1 | c.6007C>T p.P2003S | Missense Mutation (SNP) | VAF 39/425 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.067); called by muse, mutect2
- SPHKAP | c.3769G>T p.A1257S | Missense Mutation (SNP) | VAF 129/519 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAB3 | c.1518T>A p.S506R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM5 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM65 | c.1224G>T p.R408S | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TULP1 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- USP32 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDHD1 | c.2598G>C p.E866D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XRCC5 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- ZNF286A | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 39/257 reads (15%) | called by muse, mutect2, varscan2
- ZNF423 | c.2561C>A p.P854H (on ENST00000563137 / NM_001379286.1; = p.P846H on NM_015069.4) | Missense Mutation (SNP) | VAF 43/417 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ZNF521 | c.408T>A p.H136Q | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF90 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- AGAP1 | c.1470G>A p.S490= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs200415065, COSV58327768; called by muse, mutect2, varscan2
- ANKRD52 | c.1515G>A p.A505= | Silent (SNP) | VAF 11/162 reads (7%) | catalogued as rs760280028, COSV57285840; called by muse, mutect2
- BARHL2 | c.1098G>T p.G366= | Silent (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- CEACAM21 | c.834C>A p.P278= (on ENST00000401445 / NM_001098506.4; = p.P277= on NM_033543.6) | Silent (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- CHAT | c.345C>T p.V115= | Silent (SNP) | VAF 62/445 reads (14%) | catalogued as rs917815714; called by muse, mutect2, varscan2
- CNKSR2 | c.1857C>T p.S619= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- CSMD2 | c.522C>T p.H174= | Silent (SNP) | VAF 55/222 reads (25%) | catalogued as rs749023926, COSV53912233, COSV53919670; called by muse, mutect2, varscan2
- DNAH14 | c.2601T>A p.T867= (on ENST00000445597; = p.T933= on NM_001367479.1) | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- DNAH17 | c.9714C>T p.A3238= | Silent (SNP) | VAF 81/395 reads (21%) | catalogued as rs751286358, COSV67757158; called by muse, mutect2, varscan2
- DPF3 | c.852C>T p.C284= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs780577141, COSV63499088; called by muse, mutect2, varscan2
- DPPA2 | c.153A>G p.K51= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- EDNRB | c.1554C>T p.H518= (on ENST00000377211 / NM_001201397.1; = p.H428= on NM_000115.5) | Silent (SNP) | VAF 32/300 reads (11%) | catalogued as rs754498240, COSV57524420; called by muse, mutect2, varscan2
- GALNTL6 | c.126C>T p.P42= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs1457249627, COSV72552892; called by muse, mutect2, varscan2
- HCAR2 | c.366G>T p.A122= | Silent (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- KIF2B | c.747C>A p.S249= | Silent (SNP) | VAF 26/234 reads (11%) | catalogued as rs771095743; called by muse, mutect2, varscan2
- KRTAP2-2 | c.333G>A p.P111= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV101195329; called by muse, varscan2
- MDN1 | c.219G>T p.L73= | Silent (SNP) | VAF 55/246 reads (22%) | called by muse, mutect2, varscan2
- MEIS2 | c.798C>T p.D266= (on ENST00000561208 / NM_170675.5; = p.D253= on NM_002399.3) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1261255075, COSV99576193; called by muse, mutect2, varscan2
- MKLN1 | c.1095C>T p.D365= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs1167229690; called by muse, mutect2
- MMP2 | c.1584G>A p.Q528= | Silent (SNP) | VAF 195/710 reads (27%) | called by muse, mutect2, varscan2
- MYH13 | c.1629C>T p.P543= | Silent (SNP) | VAF 49/211 reads (23%) | called by muse, mutect2, varscan2
- NISCH | c.3390G>C p.S1130= | Silent (SNP) | VAF 62/247 reads (25%) | catalogued as rs374595197; called by muse, mutect2, varscan2
- NUMB | c.1320C>T p.A440= (on ENST00000355058; = p.A429= on NM_003744.5) | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as rs762666896; called by muse, mutect2, varscan2
- OSBPL2 | c.729C>A p.I243= (on ENST00000313733 / NM_144498.4; = p.I231= on NM_014835.4) | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- PDCD11 | c.1746G>A p.P582= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs371019816; called by muse, mutect2, varscan2
- PHYHIP | c.738G>T p.G246= | Silent (SNP) | VAF 19/434 reads (4%) | called by muse, mutect2
- RALGAPA1 | c.1698G>T p.R566= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- RPL4 | c.948G>A p.K316= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs1400146539; called by muse, mutect2, varscan2
- SLC5A6 | c.159G>C p.R53= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- SLC8B1 | c.1242C>A p.P414= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- TBC1D20 | c.912A>T p.P304= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- TP63 | c.1563C>A p.P521= | Silent (SNP) | VAF 38/380 reads (10%) | called by muse, mutect2
- VPS13C | c.5427C>T p.I1809= (on ENST00000644861 / NM_020821.3; = p.I1766= on NM_017684.5) | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs148320887; called by muse, mutect2, varscan2
- VPS37A | c.981A>C p.A327= | Silent (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- WDR6 | c.1209G>A p.E403= | Silent (SNP) | VAF 100/396 reads (25%) | called by muse, mutect2, varscan2
- WEE2 | c.1608G>A p.G536= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV66879949; called by muse, mutect2
- AC073348.1 | n.104C>T | RNA (SNP) | VAF 86/238 reads (36%) | catalogued as rs1236605956; called by muse, mutect2, varscan2
- C2orf91 | n.216G>T | RNA (SNP) | VAF 46/419 reads (11%) | called by muse, mutect2, varscan2
- CCNQP1 | n.357G>T | RNA (SNP) | VAF 38/792 reads (5%) | called by muse, mutect2
- DNAI4 | c.643+22A>G | Intron (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- ERLIN2 | c.425-1560C>T | Intron (SNP) | VAF 12/132 reads (9%) | catalogued as rs568318654; called by muse, mutect2
- FAM172BP | n.801C>T | RNA (SNP) | VAF 16/198 reads (8%) | catalogued as rs1051311435; called by muse, mutect2
- FRMD8P1 | n.622G>A | RNA (SNP) | VAF 33/554 reads (6%) | catalogued as rs1400339919; called by muse, mutect2
- HERC2P3 | n.820G>A | RNA (SNP) | VAF 10/85 reads (12%) | catalogued as rs545085863; called by muse, mutect2, varscan2
- IFT80 | c.-8G>A | 5'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- KSR1 | c.*28C>T | 3'UTR (SNP) | VAF 16/110 reads (15%) | catalogued as COSV52031529; called by muse, mutect2, varscan2
- LINC00544 | n.769C>A | RNA (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- LZTR1 | c.1943-340G>A | Intron (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- OR7A2P | n.422G>A | RNA (SNP) | VAF 27/99 reads (27%) | catalogued as rs762617133; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67929G>T | Intron (SNP) | VAF 54/297 reads (18%) | called by muse, mutect2, varscan2
- PRKRA | c.785-48T>G | Intron (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- SLC25A27 | c.299-75C>T | Intron (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- SV2C | c.581-20939C>A | Intron (SNP) | VAF 62/473 reads (13%) | called by muse, mutect2, varscan2
- TMC8 | c.298+120C>A | Intron (SNP) | VAF 16/160 reads (10%) | catalogued as COSV59209039; called by muse, mutect2
- ZAP70 | c.402+183G>A | Intron (SNP) | VAF 55/234 reads (24%) | called by muse, mutect2, varscan2
